HCMI case HCM-BROD-0132-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/93d1a30b-21c8-4cf7-9d51-49f6e03ef679

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 425 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.6; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Age at diagnosis: 73.1 years (26,698 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Peritoneum, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 14 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 14 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 25 days; Days to treatment end: 185 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 227 days; Days to treatment end: 235 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 0 days.
- Days to follow up: 360 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 360 days.
- Days to follow up: 425 days (1.2 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 381.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 51.3 kg; Height: 161.6 cm; BMI: 19.6.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol intensity: Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-BROD-0132-C25-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0132-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
